TCGA case TCGA-56-8623 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/513c5f34-dc6e-4caa-81cc-907fd6a825b1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 692 days (1.9 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 71.8 years (26,231 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 692 days (1.9 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 73.6 years (26,876 days); Days to diagnosis: 645 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 680 days (1.9 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 692 days (1.9 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 6.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 45.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-56-8623-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.7. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide TCGA-56-8623-01A-01-TS1: Section location: Top; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample TCGA-56-8623-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-56-8623-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-56-8623-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Peripheral Lung; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form, New neoplasm event types: New tumor event type: New Primary Tumor.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Biopsy with Histologic Confirmation.

GDC annotations on this case (curator notes; quoted as recorded):
- BCR Notification (a sample-identity caveat): Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on sample TCGA-56-8623-01A: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-56-8623-01A-11D: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-56-8623-01A-11D-2391-01: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-56-8623-01A-11D-2395-08: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-56-8623-01A-11D-2398-05: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-56-8623-01A-11H: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-56-8623-01A-11H-2402-13: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-56-8623-01A-11R: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-56-8623-01A-11R-2403-07: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on aliquot TCGA-56-8623-01A-11R-A28V-07: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- BCR Notification (a sample-identity caveat) on analyte TCGA-56-8623-01A-11W: Possible tumor/normal sample swap, cross-contamination, and/or sample purity issues. The sequencing and characterization centers have reported that molecular signature of the tumor DNA and RNA cluster with the normal controls. Their analysis suggests that the purity of the tumor is very low. Therefore, the data from this patient should be used with caution.
- (and 17 further annotations of these kinds)

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 692 days; disease-specific survival: no event (censored), 692 days; disease-free interval: no event (censored), 692 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 645 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-56-8623-01): tumor purity 0.96, ploidy 1.95, whole-genome doublings 0 (call status: maf_call).
